Somatic mutation profile of tumor specimen TCGA-AP-A1DP-01A (aliquot TCGA-AP-A1DP-01A-11D-A135-09) from TCGA case TCGA-AP-A1DP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.1 years (25,601 days).
Specimen TCGA-AP-A1DP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44571069-f57e-4933-ba6f-d6ff0f378c8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DP-10A (Blood Derived Normal), aliquot TCGA-AP-A1DP-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eabdcc18-0c7c-4cea-b4f6-b08498314f02

The open-access MAF lists 540 somatic variants for this specimen: 411 protein-altering or splice-affecting, 117 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 272, Silent 117, Frame Shift Del 89, Frame Shift Ins 24, Nonsense Mutation 15, Intron 6, Splice Region 3, 3'Flank 3, Splice Site 3, In Frame Del 3, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- CYLD | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as rs886040872, CM001113, COSV61094720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.2059G>A p.G687R (on ENST00000447712 / NM_023110.3; = p.G685R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727505376, CM055942, COSV100248222, COSV58337704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 17/28 reads (61%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.371_372del p.I124Rfs*6 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs1566186125; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TGFB2 | c.821dup p.N274Kfs*19 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ZEB1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs1057518956, CM075048, COSV58047950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4124C>G p.P1375R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101036959; called by muse, mutect2, varscan2
- ABCC10 | c.2032G>C p.A678P (on ENST00000372530 / NM_001198934.2; = p.A650P on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99767283; called by muse, mutect2, varscan2
- AC013489.1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs778994249, COSV51553273; called by muse, mutect2, varscan2
- ACKR2 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99825537; called by muse, mutect2, varscan2
- ACSF3 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441335; called by muse, mutect2, varscan2
- ADGRB2 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99926253; called by muse, mutect2, varscan2
- ADGRG1 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101113414; called by muse, mutect2, varscan2
- ADH1A | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.68); catalogued as COSV99265783; called by muse, mutect2, varscan2
- ADNP2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1427726663, COSV100080877; called by muse, mutect2, varscan2
- AGT | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs559327874, COSV100794299; called by muse, mutect2, varscan2
- AKAP11 | c.2953T>C p.S985P | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99213926; called by muse, mutect2, varscan2
- AMER1 | c.1265A>T p.N422I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100366114, COSV57665355; called by muse, mutect2, varscan2
- AMZ2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs140418249; called by muse, mutect2, varscan2
- ANAPC11 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV100485848; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs754669508, COSV99783351; called by muse, mutect2, varscan2
- ANKRD17 | c.7724G>A p.S2575N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1257897136, COSV100429214; called by muse, mutect2, varscan2
- AP1M1 | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358386; called by muse, mutect2, varscan2
- APBB1IP | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100774360; called by muse, mutect2, varscan2
- APLP2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.69); PolyPhen probably damaging (1); catalogued as rs1388511939, COSV99599707; called by muse, mutect2, varscan2
- ARHGAP4 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs782325157, COSV100604046, COSV63132593; called by muse, mutect2, varscan2
- ARHGAP44 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1337602328, COSV99310704; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ASCL4 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV60817064; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPRV1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100208503; called by muse, mutect2, varscan2
- ATAD2B | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477663; called by muse, mutect2, varscan2
- ATP1A2 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as rs370111257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100707042; called by muse, mutect2, varscan2
- ATP8A2 | c.3499G>T p.G1167* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99681988; called by muse, mutect2, varscan2
- AURKA | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100453012, COSV57170745; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs778012871; called by pindel, varscan2
- BAHCC1 | c.5677G>A p.A1893T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs532575779, COSV100311658; called by muse, mutect2, varscan2
- BCAR3 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99550756; called by muse, mutect2, varscan2
- BOD1L1 | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99239383; called by muse, mutect2, varscan2
- BPNT2 | c.550+2T>C p.X184_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | catalogued as COSV52908380; called by muse, mutect2, varscan2
- BPTF | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58831141; called by muse, mutect2, varscan2
- BRAT1 | c.566dup p.D190* | Frame Shift Ins (INS) | VAF 27/75 reads (36%) | catalogued as rs1384976053; called by mutect2, pindel, varscan2
- BRD1 | c.2728+2T>C p.X910_splice (on ENST00000216267 / NM_001349940.1; = p.X1041_splice on NM_001304808.3) | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99349772; called by muse, mutect2, varscan2
- BRD1 | c.2623C>T p.R875W (on ENST00000216267 / NM_001349940.1; = p.R1006W on NM_001304808.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs941898991, COSV53455429; called by muse, mutect2, varscan2
- BRWD1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs1350768791, COSV100313421; called by muse, varscan2
- C3 | c.3133del p.A1045Pfs*26 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as COSV99837440; called by mutect2, pindel, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs201838505; called by mutect2, varscan2
- CARMIL1 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV61519950; called by muse, mutect2, varscan2
- CCDC178 | c.371+2T>C p.X124_splice | Splice Site (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100284904; called by muse, mutect2, varscan2
- CCDC34 | c.731dup p.N244Kfs*3 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC8 | c.890del p.G297Efs*12 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs1450099223; called by mutect2, pindel, varscan2
- CD27 | c.189T>G p.D63E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99869984; called by muse, mutect2, varscan2
- CDH23 | c.3668G>A p.G1223D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771217536, COSV99821010; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV100575455; called by muse, mutect2, varscan2
- CEP72 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV99374798; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs761800837; called by mutect2, varscan2
- CHEK1 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99629649; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA4 | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV100937415; called by muse, mutect2, varscan2
- CLCN5 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as CD095957, CM104899, COSV100260131; called by muse, mutect2, varscan2
- CLMN | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100112411; called by muse, mutect2, varscan2
- CLOCK | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs774685553, COSV100011803; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs369752219; called by mutect2, varscan2
- CNOT3 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99651850; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs374805044; called by mutect2, varscan2
- COL20A1 | c.1679del p.P560Rfs*9 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs761988638; called by mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 13/27 reads (48%) | catalogued as rs760493024; called by mutect2, varscan2
- COL25A1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1030036795, COSV101211381; called by muse, mutect2, varscan2
- COL5A2 | c.3593C>A p.P1198H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880336; called by muse, mutect2, varscan2
- COL6A2 | c.2761G>A p.V921M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs398123650, COSV52424508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.6697G>A p.G2233S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM005547, CM014335, CM1410631, COSV100096270; called by muse, mutect2, varscan2
- CP | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1161226577, CD994589, COSV99224112; called by muse, mutect2, varscan2
- CPNE8 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100504378; called by muse, mutect2, varscan2
- CRISP3 | c.204A>C p.Q68H (on ENST00000371159 / NM_001368123.1; = p.Q50H on NM_006061.4) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99538950; called by muse, mutect2, varscan2
- CSMD1 | c.9379G>A p.G3127S (on ENST00000520002; = p.G3126S on NM_033225.6) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59289246, COSV59380853; called by muse, mutect2, varscan2
- CTC1 | c.3428G>A p.W1143* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100236451; called by muse, mutect2, varscan2
- CTNNB1 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV100846235; called by muse, mutect2, varscan2
- CTNND2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs757232370, COSV100476626; called by muse, varscan2
- CUBN | c.7871G>A p.S2624N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV64707960; called by muse, mutect2, varscan2
- CUL9 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs751960943, COSV99335417; called by muse, mutect2, varscan2
- CXXC1 | c.1439C>G p.T480R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV99496390; called by muse, mutect2, varscan2
- CXXC1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs763655763, COSV99496391; called by muse, mutect2, varscan2
- CYP2F1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs746849388, COSV58527059; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as COSV99245498; called by mutect2, varscan2
- DEPDC1 | c.1370del p.L457* | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs1198615001; called by mutect2, pindel, varscan2
- DFFB | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750391864, COSV58860534; called by muse, mutect2, varscan2
- DGKD | c.2213T>C p.I738T (on ENST00000264057 / NM_152879.3; = p.I694T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV99896360; called by muse, mutect2, varscan2
- DIPK2B | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1340643598, COSV100933437; called by muse, mutect2, varscan2
- DLX3 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV101460557; called by muse, mutect2, varscan2
- DMPK | c.1627_1633del p.A543Ifs*6 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs1470320084; called by mutect2, pindel, varscan2
- DNAH10 | c.6058G>A p.V2020M (on ENST00000409039; = p.V1959M on NM_207437.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1459777288, COSV68994922; called by muse, mutect2, varscan2
- DNAH3 | c.11299G>A p.A3767T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.352); catalogued as rs747868325, COSV54518219; called by mutect2, varscan2
- DNAJA4 | c.395del p.N132Mfs*2 (on ENST00000343789; = p.N161Mfs*2 on NM_018602.3) | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as COSV59425422; called by mutect2, pindel, varscan2
- DNASE1L3 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs778387758, COSV100568717; called by muse, mutect2, varscan2
- DOCK10 | c.1122dup p.D375Rfs*6 | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as rs782552436; called by pindel, varscan2
- DPH7 | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99480699; called by muse, mutect2, varscan2
- DPYSL2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs979527383, COSV60782839; called by muse, mutect2, varscan2
- DUOX2 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV101199769; called by muse, mutect2, varscan2
- EDARADD | c.610C>T p.P204S (on ENST00000334232 / NM_145861.4; = p.P194S on NM_080738.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100512676; called by muse, mutect2, varscan2
- EDC4 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1321316943, COSV100739138; called by muse, mutect2, varscan2
- EHBP1L1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769231487, COSV100499877; called by muse, mutect2, varscan2
- EHD4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs145717011; called by muse, mutect2, varscan2
- ELMOD1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99760032; called by muse, mutect2, varscan2
- ELMOD3 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as rs767120998, COSV99809428; called by muse, mutect2, varscan2
- ELP3 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99833975; called by muse, mutect2, varscan2
- EMC1 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as COSV100916445; called by muse, mutect2, varscan2
- ENOX2 | c.1297G>A p.E433K (on ENST00000338144 / NM_001382520.1; = p.E404K on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV100584142, COSV57651054; called by muse, mutect2, varscan2
- ENOX2 | c.825G>A p.W275* (on ENST00000338144 / NM_001382520.1; = p.W246* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100584144; called by muse, mutect2, varscan2
- ERC1 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV100706066; called by muse, mutect2, varscan2
- ERLEC1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373252361, COSV99483037; called by muse, mutect2, varscan2
- FBH1 | c.2813T>C p.I938T (on ENST00000362091 / NM_178150.3; = p.I989T on NM_032807.4) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100758747, COSV62983504; called by muse, mutect2, varscan2
- FNDC1 | c.5231C>T p.S1744L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369189702; called by muse, mutect2, varscan2
- FOXF2 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs142547284, COSV99453240; called by muse, mutect2, varscan2
- FOXJ2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs925597042, COSV50818109; called by muse, mutect2, varscan2
- FOXP4 | c.1579C>T p.R527C (on ENST00000307972 / NM_001012426.1; = p.R514C on NM_138457.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365508198, COSV100332260, COSV100332728; called by muse, mutect2, varscan2
- FRMD4B | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101273460; called by muse, mutect2, varscan2
- FUT1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs1334278793, COSV100038126; called by muse, mutect2, varscan2
- GAA | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1425709688, COSV100163211; called by muse, mutect2
- GALNT7 | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV99397382; called by muse, mutect2, varscan2
- GBF1 | c.3358dup p.M1120Nfs*27 (on ENST00000369983 / NM_001377137.1; = p.M1119Nfs*27 on NM_004193.3) | Frame Shift Ins (INS) | VAF 28/54 reads (52%) | catalogued as rs1210993788; called by mutect2, pindel, varscan2
- GCNA | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101032526; called by muse, mutect2, varscan2
- GINS4 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99394533; called by muse, mutect2, varscan2
- GLUL | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1288022473, COSV59382536; called by muse, mutect2, varscan2
- GPAA1 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100284061; called by muse, mutect2, varscan2
- GPAT2 | c.2048G>A p.C683Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV100853277; called by muse, mutect2, varscan2
- GPR85 | c.460T>C p.F154L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV99775199; called by muse, mutect2, varscan2
- GRIK3 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs749738235, COSV66140529; called by muse, mutect2, varscan2
- GRIN2D | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1357633359, COSV99616440; called by muse, mutect2, varscan2
- GUSB | c.1703A>C p.Q568P | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV100512624; called by muse, mutect2, varscan2
- H2BC18 | c.131A>T p.K44M | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100516098, COSV58944826; called by muse, mutect2, varscan2
- HCAR2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.855); catalogued as rs780477417, COSV100186486, COSV61024827; called by muse, mutect2, varscan2
- HDAC11 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs781222934, COSV99849911; called by muse, mutect2, varscan2
- HIGD1C | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV101268747; called by muse, mutect2, varscan2
- HLA-G | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV100827080; called by muse, mutect2, varscan2
- HSP90B1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs370313687; called by muse, mutect2, varscan2
- IGKV1-6 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1271823840; called by muse, mutect2
- IGSF9 | c.3111dup p.S1038Lfs*26 (on ENST00000368094 / NM_001135050.2; = p.S1022Lfs*26 on NM_020789.4) | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs1193773558; called by mutect2, varscan2
- IL11RA | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99426481; called by muse, mutect2, varscan2
- IL12RB2 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024536, COSV99255076; called by muse, mutect2, varscan2
- ILVBL | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs373973772; called by muse, mutect2, varscan2
- IMPG1 | c.495C>T p.D165= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100886393; called by muse, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | catalogued as rs759837481; called by mutect2, varscan2
- IPO8 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV99805315; called by muse, mutect2, varscan2
- IPO9 | c.917T>A p.V306E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100843433; called by muse, mutect2, varscan2
- IQCN | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101148647; called by muse, mutect2, varscan2
- IQGAP3 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100752148; called by muse, mutect2, varscan2
- IRF7 | c.1474A>C p.S492R (on ENST00000397566; = p.S479R on NM_001572.5) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV99200484; called by muse, mutect2, varscan2
- ISOC2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99321188; called by muse, mutect2, varscan2
- KANSL1 | c.2335C>T p.H779Y | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as COSV99294503; called by muse, mutect2, varscan2
- KANSL1L | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99910561; called by muse, mutect2, varscan2
- KAT14 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890075; called by muse, mutect2, varscan2
- KCNV2 | c.1474C>A p.L492I | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as rs748379690, COSV101172583; called by muse, mutect2, varscan2
- KCTD17 | c.560T>G p.F187C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1342909925, COSV100786761; called by muse, mutect2, varscan2
- KCTD19 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58574148; called by muse, mutect2, varscan2
- KDM2B | c.1030A>C p.I344L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV100997414; called by muse, mutect2, varscan2
- KEL | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs61729057, CM024404, COSV100787078; called by muse, mutect2, varscan2
- KIF13B | c.3220C>T p.H1074Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as COSV101580686; called by muse, mutect2, varscan2
- KIF16B | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734298; called by muse, mutect2, varscan2
- KIF21A | c.2805G>A p.M935I (on ENST00000361418 / NM_001378440.1; = p.M922I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100735469; called by muse, mutect2, varscan2
- KIRREL3 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101585729; called by muse, mutect2, varscan2
- KMT2B | c.7336C>T p.R2446* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV55820343; called by muse, mutect2, varscan2
- KMT2D | c.10324G>T p.G3442C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56455564, COSV99981837; called by muse, mutect2, varscan2
- LCT | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777321408, COSV51545956; called by muse, mutect2, varscan2
- LOXL3 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as COSV99239675; called by muse, mutect2, varscan2
- LRRC37A3 | c.4046G>A p.S1349N | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100141034; called by muse, mutect2, varscan2
- LRRTM2 | c.309T>A p.D103E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.696); catalogued as COSV99217791; called by muse, mutect2, varscan2
- MACF1 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs201272174, COSV99244427; called by muse, mutect2, varscan2
- MAGEB3 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV100854698; called by muse, mutect2
- MAGI1 | c.4330C>T p.H1444Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as rs1334875069, COSV100441030; called by muse, mutect2, varscan2
- MAML2 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 65/104 reads (63%) | catalogued as COSV101594111; called by muse, mutect2, varscan2
- MAP3K15 | c.1211T>A p.I404N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100134749; called by muse, mutect2, varscan2
- MCUR1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63957836; called by muse, mutect2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs750092100; called by mutect2, varscan2
- MEGF10 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV99174954; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MON2 | c.4949G>A p.S1650N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as rs774812545, COSV99742575; called by muse, mutect2, varscan2
- MORC4 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99717195; called by muse, mutect2, varscan2
- MPEG1 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99915435; called by muse, mutect2, varscan2
- MROH5 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.46); catalogued as rs765080986, COSV71302911; called by muse, mutect2, varscan2
- MTREX | c.2317G>T p.G773C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100044039, COSV100044551; called by muse, mutect2, varscan2
- MTSS1 | c.2177C>A p.P726Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV99412803; called by muse, mutect2, varscan2
- MUC16 | c.40292A>G p.D13431G | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs752159006, COSV101109901; called by muse, mutect2, varscan2
- MUC16 | c.6734A>T p.E2245V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV101199957; called by muse, varscan2
- MUC16 | c.6637A>T p.T2213S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101199959; called by muse, varscan2
- MUC5B | c.17210G>T p.C5737F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101500335; called by muse, mutect2, varscan2
- MYH10 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99345233; called by muse, mutect2, varscan2
- MYH11 | c.3929T>C p.V1310A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV100258973; called by muse, mutect2, varscan2
- MYH6 | c.798C>A p.T266= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100676380; called by muse, mutect2, varscan2
- NBAS | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372517600; called by muse, mutect2, varscan2
- NBEA | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.066); catalogued as COSV100080266; called by muse, mutect2, varscan2
- NCR3 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99279048; called by muse, mutect2, varscan2
- NDUFA10 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401434; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs753934412; called by mutect2, pindel
- NOXRED1 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100033102; called by muse, mutect2, varscan2
- NRDC | c.1087A>C p.I363L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100703385; called by muse, mutect2, varscan2
- NSUN7 | c.605T>C p.L202S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100349216; called by muse, mutect2, varscan2
- NUCB1 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1482321712, COSV54385695, COSV99617882; called by muse, mutect2, varscan2
- NUP210 | c.5048C>G p.A1683G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as COSV99596212; called by muse, mutect2, varscan2
- OBSCN | c.14602G>T p.G4868C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99478127; called by muse, mutect2, varscan2
- OGDHL | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100934323; called by muse, mutect2, varscan2
- OGT | c.371A>C p.D124A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV101035403; called by muse, mutect2, varscan2
- OPTN | c.935A>C p.E312A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99537482; called by muse, mutect2, varscan2
- OR4D6 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100271705; called by muse, mutect2, varscan2
- OR5A1 | c.266_268del p.F89del | In Frame Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1367795210; called by pindel, varscan2
- OR5AU1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs770109208, COSV100436132; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs747074822; called by mutect2, varscan2
- OSMR | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as COSV57082708; called by muse, mutect2, varscan2
- OTUD6A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57973757; called by muse, mutect2, varscan2
- PAX1 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1311258575, COSV68271246; called by muse, mutect2, varscan2
- PCDHA8 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100969361, COSV65328168; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs782213177; called by mutect2, pindel, varscan2
- PCF11 | c.606A>T p.Q202H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100018401; called by muse, mutect2, varscan2
- PCNX3 | c.4990G>A p.A1664T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1231142960, COSV100856405; called by muse, mutect2, varscan2
- PDE1B | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226386; called by muse, mutect2, varscan2
- PDLIM2 | c.209G>A p.R70H (on ENST00000397760; = p.R320H on NM_021630.6) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs574512829, COSV99747614; called by muse, mutect2, varscan2
- PEX5L | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99828763; called by muse, mutect2, varscan2
- PF4 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs915500046, COSV99933096; called by muse, varscan2
- PGBD4 | c.1102dup p.R368Kfs*14 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs760924179; called by mutect2, varscan2
- PGGHG | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101164471; called by muse, mutect2, varscan2
- PHF21A | c.1879G>A p.G627S (on ENST00000418153 / NM_001101802.3; = p.G581S on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs376981110; called by muse, mutect2, varscan2
- PHKA2 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV101177065; called by muse, mutect2, varscan2
- PI4KA | c.5535G>T p.Q1845H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99746121; called by muse, mutect2, varscan2
- PIK3CA | c.1799A>T p.E600V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99837659; called by muse, mutect2, varscan2
- PIK3R3 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99421961; called by muse, mutect2, varscan2
- PKHD1L1 | c.12191C>A p.A4064D | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV101006145; called by muse, mutect2, varscan2
- PLCD4 | c.2192A>G p.H731R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101346895; called by muse, mutect2, varscan2
- PLXNA4 | c.4249C>A p.L1417M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100324338; called by muse, mutect2, varscan2
- POP1 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs142902409; called by muse, mutect2, varscan2
- POT1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1358511734, COSV100714059; called by muse, mutect2, varscan2
- PPL | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100630790, COSV62048270; called by muse, mutect2, varscan2
- PPP1R15A | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV99566051; called by muse, mutect2, varscan2
- PPP3R2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs767514182, COSV62455270; called by muse, mutect2, varscan2
- PRKAG1 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV100305157; called by muse, mutect2, varscan2
- PRR12 | c.2660A>G p.K887R (on ENST00000615927; = p.K1708R on NM_020719.3) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV101330676; called by muse, mutect2, varscan2
- PSMB10 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs372222842, COSV99344650; called by muse, mutect2, varscan2
- PTPRC | c.3527C>T p.T1176M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773582172, COSV100722019; called by muse, mutect2, varscan2
- PTPRF | c.4165C>A p.H1389N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100740461, COSV100740909; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769450409, COSV99424727; ClinVar: uncertain significance; called by muse, mutect2
- RALGAPA2 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173612; called by muse, varscan2
- RALGAPB | c.1724T>C p.L575S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777362405, COSV99485252; called by muse, mutect2, varscan2
- RAP1GAP | c.1045del p.L349Sfs*18 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs753793537; called by mutect2, pindel, varscan2
- RASAL1 | c.2413T>C p.*805Qext*33 | Nonstop Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99921727; called by muse, mutect2, varscan2
- RASAL2 | c.3227A>G p.D1076G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100862628; called by muse, mutect2, varscan2
- RASL10A | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as COSV99329519; called by muse, mutect2, varscan2
- RBBP5 | c.261T>A p.D87E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99196810; called by muse, mutect2, varscan2
- RBM15 | c.1417C>G p.R473G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV100873446; called by muse, mutect2, varscan2
- RBM26 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV57392149; called by muse, mutect2, varscan2
- RELN | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.642); catalogued as COSV100633757; called by muse, mutect2
- RGL1 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100486772; called by muse, mutect2, varscan2
- RIC1 | c.3724C>T p.Q1242* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99317284; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF25 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs747257692, COSV55306073; called by muse, mutect2, varscan2
- RNF40 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100222093; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.350del p.R117Pfs*41 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV68457011, COSV68457480, COSV99064540; called by mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RNH1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.511); catalogued as rs1390982516, COSV100596747; called by muse, mutect2, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs1192824348; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.2257C>T p.L753F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100955072; called by muse, mutect2, varscan2
- RPS6KA2 | c.60A>G p.I20M | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.135); catalogued as COSV72313304; called by muse, mutect2, varscan2
- RTEL1 | c.3223G>A p.G1075S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1431515751, COSV99422987; called by muse, mutect2, varscan2
- RXFP3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100347542; called by muse, mutect2, varscan2
- SALL4 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs746545323, COSV99409519; called by muse, mutect2, varscan2
- SAMD4A | c.1649A>C p.Q550P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV99200678; called by muse, mutect2, varscan2
- SCAPER | c.2613dup p.A872Sfs*13 | Frame Shift Ins (INS) | VAF 26/56 reads (46%) | catalogued as rs757259031; called by mutect2, varscan2
- SCARB1 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as rs760512991, COSV99909269; called by muse, mutect2, varscan2
- SECISBP2L | c.1413dup p.L472Ifs*14 (on ENST00000559471 / NM_001193489.2; = p.L427Ifs*14 on NM_014701.4) | Frame Shift Ins (INS) | VAF 29/71 reads (41%) | catalogued as rs768725524; called by mutect2, varscan2
- SEPTIN9 | c.578C>A p.P193H (on ENST00000427177 / NM_001113491.2; = p.P175H on NM_006640.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV100217976; called by muse, mutect2, varscan2
- SGCA | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as rs375692868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKIV2L | c.851C>G p.A284G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100952733; called by muse, mutect2, varscan2
- SKOR1 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as COSV58244371; called by muse, mutect2, varscan2
- SLC12A3 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV99344247; called by muse, mutect2, varscan2
- SLC22A9 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1243855842, COSV99655017; called by muse, mutect2, varscan2
- SLC30A9 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs143375647; called by muse, mutect2, varscan2
- SLC38A9 | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100591406, COSV100591456; called by muse, mutect2, varscan2
- SLC41A1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV100900395; called by muse, mutect2, varscan2
- SLC6A20 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100653716; called by muse, mutect2, varscan2
- SLC6A7 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100046291; called by muse, mutect2, varscan2
- SLITRK3 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV53850011, COSV99579248; called by muse, mutect2, varscan2
- SMARCC2 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99911344; called by muse, mutect2, varscan2
- SMARCD1 | c.249del p.N84Tfs*79 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as COSV104391003, COSV99948091; called by mutect2, varscan2
- SNRK | c.1990T>C p.Y664H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99939109; called by muse, mutect2, varscan2
- SNTG2 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV100422623; called by muse, mutect2, varscan2
- SNUPN | c.1015C>A p.L339M | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100419392; called by muse, mutect2, varscan2
- SORCS2 | c.2731G>A p.G911S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs768340326, COSV61184232; called by muse, mutect2, varscan2
- SOX15 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs763593451, COSV51468670; called by muse, mutect2, varscan2
- SPATA31A3 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs960499104; called by mutect2, varscan2
- SPON1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100115847; called by muse, mutect2, varscan2
- SPRY4 | c.308G>A p.S103N (on ENST00000434127 / NM_001127496.3; = p.S126N on NM_030964.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100702182; called by muse, mutect2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 14/23 reads (61%) | catalogued as rs751748506; called by mutect2, varscan2
- ST14 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs774611637, COSV99598446, COSV99598751; called by muse, mutect2, varscan2
- STAT1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs781389511, CM108248, COSV100738643; called by muse, mutect2, varscan2
- STRIP1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV100873967; called by muse, mutect2, varscan2
- STXBP3 | c.529A>G p.M177V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs748177759, COSV100893983; called by muse, mutect2, varscan2
- SUB1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs772309920, COSV54082732; called by muse, mutect2, varscan2
- SULT1A2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs376675029, COSV100187146; called by muse, mutect2, varscan2
- SYMPK | c.724T>G p.F242V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99841735; called by muse, mutect2, varscan2
- TACR1 | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100537907; called by muse, mutect2, varscan2
- TATDN3 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100875216; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCHH | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs201179054, COSV64276945; called by muse, mutect2, varscan2
- TCHH | c.4277A>G p.Q1426R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV100915059; called by muse, mutect2, varscan2
- TERT | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs939537185, COSV57238094; called by muse, mutect2, varscan2
- TESMIN | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV99663391; called by muse, mutect2, varscan2
- THRAP3 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100663385; called by muse, mutect2, varscan2
- THRAP3 | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100663387; called by muse, mutect2, varscan2
- TIAM1 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV54544043, COSV99735127; called by muse, mutect2, varscan2
- TMEM200A | c.1438A>G p.N480D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV99759299; called by muse, mutect2, varscan2
- TMEM44 | c.965A>G p.Q322R (on ENST00000392432 / NM_001166305.2; = p.Q275R on NM_138399.5) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1207918951, COSV99861832; called by muse, mutect2, varscan2
- TNFAIP3 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs373799889; called by muse, mutect2, varscan2
- TNS1 | c.4889C>A p.P1630H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99410719; called by muse, mutect2, varscan2
- TPO | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs750068617, COSV61094907; called by muse, mutect2, varscan2
- TRHR | c.431del p.K144Rfs*33 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as COSV61233337; called by mutect2, pindel, varscan2
- TRIO | c.4862A>G p.D1621G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751338228, COSV100710373; called by muse, mutect2, varscan2
- TRRAP | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs782247663, COSV100722489; called by muse, mutect2, varscan2
- UIMC1 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101022158; called by muse, mutect2, varscan2
- UNC5B | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs766852918, COSV100100746; called by muse, mutect2, varscan2
- UNC79 | c.843G>A p.W281* (on ENST00000393151 / NM_001346218.2; = p.W104* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99827882; called by muse, mutect2, varscan2
- UNKL | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100061485, COSV57019926; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 24/42 reads (57%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.12496G>A p.V4166M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs746419426, COSV100234759; called by muse, mutect2, varscan2
- USH2A | c.5620G>A p.V1874I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs200923150, CD1110210, COSV100234763; called by muse, mutect2
- USP26 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100896633; called by muse, mutect2, varscan2
- USP9X | c.5364del p.K1788Nfs*10 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as COSV61075559; called by pindel, varscan2
- WWC3 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV101081453; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1166941994; called by mutect2, pindel, varscan2
- ZBTB5 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs11558453, COSV57039618; called by muse, mutect2, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFHX3 | c.314dup p.P106Afs*13 | Frame Shift Ins (INS) | VAF 27/67 reads (40%) | catalogued as rs769936196; called by mutect2, pindel, varscan2
- ZFYVE26 | c.5402C>A p.A1801E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100720417; called by muse, mutect2, varscan2
- ZNF106 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99782602; called by muse, mutect2, varscan2
- ZNF200 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs574414063, COSV67724106; called by muse, mutect2, varscan2
- ZNF451 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs141453646; called by muse, mutect2, varscan2
- ZNF557 | c.851A>G p.H284R (on ENST00000414706 / NM_001044388.2; = p.H291R on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as COSV53273990; called by muse, mutect2, varscan2
- ZNF582 | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100018709; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs749473342; called by mutect2, varscan2
- ZSWIM5 | c.3047C>T p.A1016V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV99870200; called by muse, mutect2, varscan2
- ZSWIM8 | c.3623G>A p.R1208Q (on ENST00000605216 / NM_001242487.2; = p.R1213Q on NM_015037.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs776355230, COSV55213598; called by muse, mutect2, varscan2
- ACSS1 | c.1486del p.A496Pfs*103 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- AHNAK2 | c.15167del p.G5056Vfs*30 | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | called by mutect2, varscan2
- BAZ2B | c.5221_5222del p.E1741Kfs*22 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- C1QTNF6 | c.241del p.H81Tfs*15 | Frame Shift Del (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- CDH10 | c.1251del p.I418Lfs*60 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- CDYL | c.40del p.S14Afs*17 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, pindel, varscan2
- CHKB | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP1 | c.786_795dup p.V266Lfs*38 | Frame Shift Ins (INS) | VAF 19/44 reads (43%) | called by mutect2, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, varscan2
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- DHRS7 | c.439_440del p.C147Hfs*15 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by pindel, varscan2
- DHX9 | c.837_838del p.Q280Rfs*16 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | called by pindel, varscan2
- DMXL1 | c.4927del p.Y1643Tfs*4 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | called by pindel, varscan2
- FAM111A | c.588_590del p.R197del | In Frame Del (DEL) | VAF 12/26 reads (46%) | called by pindel, varscan2
- FAT4 | c.7542del p.K2514Nfs*7 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- FGFR2 | c.518dup p.N173Kfs*27 | Frame Shift Ins (INS) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- FSD2 | c.298del p.V100Ffs*8 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1228del p.V410Ffs*12 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- GABBR2 | c.2567del p.N856Ifs*24 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- GABRG2 | c.498del p.N167Tfs*4 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- HSPA13 | c.543del p.K181Nfs*15 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- INSRR | c.2264del p.G755Afs*20 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- IRF9 | c.151dup p.R51Pfs*16 | Frame Shift Ins (INS) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580dup p.P861Tfs*4 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- KIF7 | c.1702del p.L568Wfs*31 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- LAMP1 | c.1051del p.S351Qfs*33 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | called by mutect2, pindel, varscan2
- LRRIQ3 | c.1603dup p.I535Nfs*2 | Frame Shift Ins (INS) | VAF 40/88 reads (45%) | called by mutect2, pindel, varscan2
- MAPK4 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MET | c.4039dup p.E1347Gfs*28 | Frame Shift Ins (INS) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- MTSS1 | c.459dup p.G154Rfs*4 | Frame Shift Ins (INS) | VAF 34/63 reads (54%) | called by mutect2, varscan2
- NCKIPSD | c.812del p.P271Lfs*23 | Frame Shift Del (DEL) | VAF 27/49 reads (55%) | called by mutect2, pindel, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | called by mutect2, varscan2
- NRXN1 | c.2324del p.R775Lfs*2 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- OR1A2 | c.746del p.L249Yfs*14 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- OR4C13 | c.61del p.M21Cfs*17 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, pindel, varscan2
- OTUD7B | c.1730del p.P577Qfs*16 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- P2RY14 | c.594_595del p.F199Sfs*16 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by pindel, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.5216del p.K1739Rfs*56 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- PLEKHA3 | c.861del p.K287Nfs*24 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PROX1 | c.126del p.F42Lfs*4 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- PTEN | c.27del p.S10Afs*14 | Frame Shift Del (DEL) | VAF 26/42 reads (62%) | called by mutect2, pindel, varscan2
- RAI1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- RBBP6 | c.4423del p.T1475Lfs*20 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- SLC28A2 | c.1183del p.V395* | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.212dup p.L71Ffs*23 | Frame Shift Ins (INS) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.3094del p.Q1032Sfs*29 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.2348del p.L783Wfs*8 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | called by mutect2, pindel, varscan2
- TIMM44 | c.249del p.K83Nfs*9 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- TMEM67 | c.338del p.N113Tfs*9 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- TNFRSF10D | c.656del p.L219* | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- TRIM9 | c.142del p.Q48Rfs*21 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- TSC22D1 | c.711_713del p.H238del | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
- TUBGCP2 | c.2647del p.Q883Kfs*25 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- ZCCHC8 | c.219del p.K73Nfs*2 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- ZDHHC15 | c.672del p.F224Lfs*5 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- ZFHX3 | c.3429del p.R1143Sfs*44 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- ZNF569 | c.389del p.F130Sfs*17 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ABCA1 | c.5085T>C p.P1695= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV101036957; called by muse, mutect2, varscan2
- ABTB1 | c.1081C>T p.L361= (on ENST00000232744 / NM_172027.3; = p.L219= on NM_032548.3) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99229811; called by muse, mutect2, varscan2
- ADAMTS13 | c.2196G>A p.A732= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs781888677, COSV100747083; called by muse, mutect2, varscan2
- ANLN | c.2865T>C p.T955= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV99732308; called by muse, mutect2
- ANO3 | c.1494C>T p.T498= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99882883; called by muse, mutect2, varscan2
- AOC3 | c.73C>T p.L25= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs1174010571, COSV99520151; called by muse, mutect2, varscan2
- APP | c.1002A>G p.E334= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100695758; called by muse, mutect2, varscan2
- ATP5F1A | c.249C>T p.R83= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs572709272, COSV56361894; called by muse, mutect2, varscan2
- BICRAL | c.1269A>G p.Q423= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1002082192, COSV100018074; called by muse, mutect2, varscan2
- BMP10 | c.531T>C p.N177= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99770408; called by muse, mutect2, varscan2
- BPTF | c.987G>T p.V329= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100074981; called by muse, mutect2, varscan2
- BRIP1 | c.2598G>A p.Q866= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs769021796, COSV99370179; ClinVar: likely benign; called by muse, mutect2, varscan2
- C15orf39 | c.288G>A p.S96= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs200766020, COSV62295668; called by muse, mutect2, varscan2
- C8orf58 | c.1026C>T p.R342= (on ENST00000289989 / NM_001013842.3; = p.R334= on NM_173686.3) | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV99254590; called by muse, mutect2, varscan2
- CALML5 | c.213G>A p.T71= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs935990248, COSV66702677; called by muse, mutect2, varscan2
- CAPN13 | c.69C>T p.T23= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs771334705, COSV54435597, COSV99700246; called by muse, mutect2, varscan2
- CAPRIN2 | c.1860G>A p.L620= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV51832328; called by muse, mutect2, varscan2
- CARD11 | c.2245C>T p.L749= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100829064, COSV100829185; called by muse, mutect2, varscan2
- CCM2 | c.567C>A p.P189= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV51851223, COSV99347829; called by muse, mutect2, varscan2
- CD163L1 | c.1761C>T p.G587= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs926502193, COSV58011231; called by muse, mutect2, varscan2
- CEACAM16 | c.546C>T p.D182= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs747829770, COSV101312698; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRFAM7A | c.600A>G p.V200= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100241604; called by muse, mutect2, varscan2
- CHRNB2 | c.675G>A p.T225= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs994716085, COSV63807749; called by muse, mutect2, varscan2
- CHRNB3 | c.594C>T p.N198= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs544144336, COSV51494038; called by muse, mutect2, varscan2
- CLCNKB | c.1005C>T p.L335= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1175327320, COSV100990246; called by muse, mutect2, varscan2
- COL23A1 | c.378C>T p.R126= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs564979860, COSV101178492; called by muse, mutect2, varscan2
- CPZ | c.1122G>A p.V374= (on ENST00000360986 / NM_001014447.3; = p.V363= on NM_003652.3) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs138876879; called by muse, mutect2, varscan2
- CRISPLD2 | c.1188T>C p.A396= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99295661; called by muse, mutect2, varscan2
- CST4 | c.12T>A p.P4= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99463229; called by muse, mutect2, varscan2
- CYP2E1 | c.886C>T p.L296= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99428986; called by muse, mutect2, varscan2
- DGCR2 | c.309G>A p.A103= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs149916218; called by muse, mutect2, varscan2
- ENOX1 | c.295C>T p.L99= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV54922039, COSV99816021; called by muse, mutect2, varscan2
- EPHA7 | c.804C>T p.G268= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100992398; called by muse, mutect2, varscan2
- ESS2 | c.807C>T p.A269= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs745838136, COSV99350891; called by mutect2, varscan2
- FCMR | c.672G>A p.T224= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as rs201210909, COSV100892892; called by muse, mutect2, varscan2
- FCRL1 | c.534T>C p.A178= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100839785; called by muse, mutect2, varscan2
- FGD3 | c.1488C>T p.D496= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100490571; called by muse, mutect2, varscan2
- FLNB | c.5817G>A p.T1939= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs755062959, COSV99913259; called by muse, mutect2, varscan2
- FN1 | c.2760C>T p.D920= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs764538393, COSV100117125; called by muse, mutect2, varscan2
- GALNT18 | c.834A>T p.P278= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99924623; called by muse, mutect2, varscan2
- GEMIN5 | c.3234A>G p.V1078= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV99593897; called by muse, mutect2, varscan2
- H2AC21 | c.231G>A p.T77= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100479914; called by muse, mutect2, varscan2
- HEATR6 | c.2475C>T p.S825= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99482331; called by muse, mutect2, varscan2
- HECTD1 | c.4392A>G p.L1464= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101237383; called by muse, mutect2, varscan2
- HIVEP2 | c.1857C>T p.S619= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs200807945, COSV99173523; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFI16 | c.492C>T p.G164= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV99857576; called by muse, mutect2, varscan2
- JAKMIP3 | c.2301G>A p.E767= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs1381006300, COSV100059185; called by muse, mutect2, varscan2
- KCNH8 | c.1024C>T p.L342= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV60458556; called by muse, mutect2, varscan2
- KCTD9 | c.346C>T p.L116= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV99648567; called by muse, mutect2, varscan2
- KIAA1841 | c.747G>A p.Q249= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99693712; called by muse, mutect2, varscan2
- KRT5 | c.1059C>T p.S353= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99358029; called by muse, mutect2, varscan2
- LCP1 | c.1474C>T p.L492= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100549887; called by muse, mutect2, varscan2
- LGALS12 | c.90G>A p.T30= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV55370503; called by muse, mutect2, varscan2
- LIN37 | c.426G>A p.P142= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1283377672, COSV99137444; called by muse, mutect2, varscan2
- LRP2 | c.1959C>T p.S653= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV99788503; called by muse, mutect2, varscan2
- LRP8 | c.1290C>T p.H430= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs139974918; called by muse, mutect2, varscan2
- LRRC8C | c.1602C>A p.T534= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100968244, COSV65002345; called by muse, mutect2, varscan2
- MED22 | c.354G>A p.T118= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs587654518, COSV100034690; called by muse, mutect2, varscan2
- MLLT10 | c.111C>T p.N37= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV100308162; called by muse, mutect2, varscan2
- MNAT1 | c.150T>C p.G50= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs1212661682, COSV99710230; called by muse, mutect2, varscan2
- MORN5 | c.270G>A p.R90= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV101055800; called by muse, mutect2, varscan2
- MPDZ | c.4173A>G p.R1391= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100056831; called by muse, mutect2, varscan2
- MSMP | c.222C>A p.G74= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100960214, COSV65238740; called by muse, mutect2, varscan2
- MYH6 | c.3504G>A p.K1168= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV62448226; called by muse, mutect2, varscan2
- MYO18B | c.177T>C p.A59= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100123680; called by muse, mutect2, varscan2
- MYOG | c.456C>T p.G152= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs762374484, COSV99613941; called by muse, mutect2, varscan2
- NAPG | c.579T>C p.C193= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV100529793; called by muse, mutect2, varscan2
- NCAPG | c.2835T>C p.T945= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV99265961; called by muse, mutect2, varscan2
- NCOA1 | c.75C>T p.D25= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs977250256, COSV99946049; called by muse, mutect2, varscan2
- NECTIN1 | c.1116C>T p.G372= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs373835221; called by muse, mutect2, varscan2
- NKAPL | c.39C>T p.I13= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV59199852; called by muse, mutect2, varscan2
- NLGN3 | c.1000C>T p.L334= (on ENST00000358741 / NM_181303.2; = p.L314= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100704767; called by muse, mutect2, varscan2
- NOS2 | c.3456G>A p.A1152= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs565861247, COSV100569666; called by muse, mutect2, varscan2
- NRXN2 | c.2961G>A p.L987= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99634198; called by muse, mutect2, varscan2
- NT5M | c.624C>T p.R208= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs376072879; called by muse, mutect2, varscan2
- OBSCN | c.9474C>A p.T3158= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99478123; called by muse, mutect2
- OR4C11 | c.438C>A p.A146= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as rs1169852561, COSV100155332; called by muse, mutect2, varscan2
- OTOL1 | c.1194G>A p.G398= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs370017835; called by muse, mutect2, varscan2
- PANX2 | c.408C>T p.Y136= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs776678689, COSV99348295; called by muse, mutect2, varscan2
- PCDH17 | c.3309G>A p.V1103= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs1310284591, COSV100931652, COSV64973015; called by muse, mutect2, varscan2
- PCDHA2 | c.2253G>A p.S751= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs782152702, COSV65371636; called by muse, mutect2, varscan2
- PIWIL2 | c.378G>A p.L126= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100769404; called by muse, mutect2, varscan2
- PLXNA3 | c.1113G>A p.K371= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100859986, COSV63755649; called by muse, mutect2, varscan2
- PPP4R1 | c.1689A>G p.L563= (on ENST00000400556 / NM_001042388.3; = p.L546= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs770760576, COSV99553494; called by muse, mutect2, varscan2
- PRAMEF19 | c.720C>T p.S240= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as rs1484326794; called by muse, mutect2, varscan2
- PRPF8 | c.246C>T p.R82= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs759458143, COSV100517497; called by muse, mutect2, varscan2
- RASA1 | c.1527C>T p.S509= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs777268855, COSV99169831; called by muse, mutect2, varscan2
- RECQL | c.198C>T p.A66= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs754948157, COSV100131265; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFLNB | c.75G>A p.E25= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV100225062; called by muse, mutect2, varscan2
- RHOU | c.616T>C p.L206= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- RPGRIP1L | c.2121C>T p.S707= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs771201854, COSV50906028; called by muse, mutect2, varscan2
- RTBDN | c.157C>T p.L53= (on ENST00000393233 / NM_001270444.1; = p.L85= on NM_031429.2) | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV100530788; called by muse, mutect2, varscan2
- SCN3A | c.4926C>T p.R1642= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs1427597215, COSV99327022; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERTAD4 | c.681A>G p.S227= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100882615; called by muse, mutect2, varscan2
- SFRP2 | c.723C>T p.D241= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99923325; called by muse, mutect2, varscan2
- SHCBP1 | c.1863C>A p.A621= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV100317276; called by muse, mutect2, varscan2
- SIX6 | c.381C>T p.D127= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59803428; called by muse, mutect2, varscan2
- SON | c.1755G>A p.S585= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs1262774254, COSV99278411; called by muse, mutect2, varscan2
- SOX9 | c.36C>T p.D12= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99818442; called by muse, mutect2, varscan2
- SYNM | c.3198G>A p.R1066= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV100018749; called by muse, mutect2, varscan2
- TCN2 | c.309C>T p.G103= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99308557; called by muse, mutect2, varscan2
- TERF2 | c.528T>C p.N176= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99651474; called by muse, mutect2, varscan2
- TESK2 | c.1080T>C p.R360= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV100517367; called by muse, mutect2, varscan2
- TEX26 | c.132G>A p.V44= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100994078; called by muse, mutect2
- TGFB3 | c.1065C>T p.D355= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV99472526; called by muse, mutect2, varscan2
- THOP1 | c.783G>A p.T261= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs200372786, COSV100310582; called by muse, mutect2, varscan2
- TMEM163 | c.408G>A p.L136= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1183452762, COSV99926302; called by muse, mutect2, varscan2
- TRIM32 | c.315G>A p.R105= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57767546; called by muse, mutect2, varscan2
- UEVLD | c.201A>G p.T67= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1167929782, COSV100260908; called by muse, mutect2, varscan2
- VIPR1 | c.135G>A p.V45= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100285628; called by muse, mutect2, varscan2
- WIPI2 | c.120T>G p.A40= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99993328; called by muse, mutect2, varscan2
- XPOT | c.1698T>A p.I566= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100225527; called by muse, mutect2, varscan2
- ZBTB4 | c.936G>A p.A312= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs147452733; called by muse, mutect2, varscan2
- ZNF366 | c.2085C>T p.G695= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV100574263; called by muse, mutect2, varscan2
- ZNF536 | c.2943G>A p.R981= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100835240; called by muse, mutect2, varscan2
- ZNF768 | c.1470C>T p.C490= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV100776255; called by muse, mutect2, varscan2
- ZSWIM4 | c.2193G>T p.T731= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV54325081, COSV99584895; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824442 del T | 5'Flank (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- AL353804.7 | chrX:73852247 G>T | 3'Flank (SNP) | VAF 42/81 reads (52%) | called by muse, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 6/14 reads (43%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- BRD9 | c.401-15del | Intron (DEL) | VAF 16/45 reads (36%) | catalogued as rs747777302, COSV51319227; called by mutect2, varscan2
- COL5A1 | c.654+7388G>A | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs777865964, COSV100879955; called by muse, mutect2, varscan2
- IGHG1 | chr14:105740087 G>A | 3'Flank (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2219G>A | Intron (SNP) | VAF 13/48 reads (27%) | catalogued as rs374982677, COSV52788551; called by muse, mutect2, varscan2
- POM121 | chr7:72948718 C>A | 3'Flank (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- RYR2 | c.11145+1273dup | Intron (INS) | VAF 13/112 reads (12%) | called by mutect2, varscan2
- SNORD113-2 | n.51A>T | RNA (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- SNORD115-37 | n.37dup | RNA (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- VPS13D | c.13035+191C>T | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99166612; called by muse, mutect2, varscan2
